MMRF case MMRF_2289 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9c599920-9ed4-4810-9dab-ea23df6e1015

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.7 years (19,246 days); ISS stage: I; Days to last known disease status: 760 days (2.1 years); Days to last follow up: 760 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 239 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 239 days; Days to treatment end: 358 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 359 days; Days to treatment end: 431 days (1.2 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 442 days (1.2 years); Days to treatment end: 442 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 443 days (1.2 years); Days to treatment end: 443 days (1.2 years).
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 550 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 721 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 131 mg/dL; Immunoglobulin G 8.48 g/L; Immunoglobulin A 1.9 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2.96 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 258 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.73 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 6.71 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 82 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.716 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 8.47 mmol/L.
- Day 155 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 5.89 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 12.2 mmol/L.
- Day 267 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 8.31 mmol/L.
- Day 351 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 79.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.667 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 1.8 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 431 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.684 mg/dL; Immunoglobulin G 6.73 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 7.37 mmol/L.
- Day 501 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.65 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.2 g/dL; Glucose 6.38 mmol/L.
- Day 645 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.797 mg/dL; Immunoglobulin G 9.22 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 7.48 mmol/L.
- Day 708: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.809 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.749 mg/dL; Immunoglobulin G 7.75 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 7.98 mmol/L.
- Day 760 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.889 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.766 mg/dL; Immunoglobulin G 8.55 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.99 mmol/L.

Other clinical attributes
- Day -6: Weight: 102 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_2289_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2289_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
